Gene-level copy-number profile of tumor specimen C3N-00656-54 from CPTAC case C3N-00656, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 62.0 years (22,663 days).
Specimen C3N-00656-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d158055f-8b36-4304-acf8-c0dcd6330605.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00656-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/dd4e9ddd-8f04-4a1e-80f2-c228fc0e2a3f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 158; copy number 2: 58,117; copy number 3: 106; copy number 4: 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,414,855–7,706,113, 18 genes: DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC084121.1, OR7E154P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 158. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
